HCMI case HCM-BROD-1130-C06 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of mouth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cb56773d-4a53-4313-8c10-51254698b3bd

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1939; Vital status: Dead; Days to death: 408 days (1.1 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C06.0; Tissue or organ of origin: Mouth, NOS; Site of resection or biopsy: Tongue, NOS; Classification of tumor: primary; Age at diagnosis: 76.9 years (28,095 days); AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Residual disease: R2; Sites of involvement: Lymph Node, Regional; Tumor depth: 26 mm; Tumor focality: Unifocal.
   Pathology details: Additional pathology findings: Keratinizing dysplasia, moderate; Lymph nodes positive: 1; Lymph nodes tested: 9; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Tumor largest dimension diameter: 6 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days; Margin distance: 4.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 60 days; Days to treatment end: 102 days.
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contacts recording only the day: day 354, day 408.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 94 kg; Height: 170 cm; BMI: 32.5.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking quit year: 2016; Alcohol intensity: Non-Drinker.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample HCM-BROD-1130-C06-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 15.
